Somatic mutation profile of tumor specimen MMRF_1533_1_BM_CD138pos (aliquot MMRF_1533_1_BM_CD138pos_T2_KBS5U_K11925) from MMRF case MMRF_1533, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.7 years (24,012 days).
Specimen MMRF_1533_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd3476f8-695a-4276-9253-83d38ce99d5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1533_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1533_1_PB_Whole_C7_KBS5U_K11899; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7083bc69-4eaa-4110-b4db-15d6928f7cc2

The open-access MAF lists 138 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 33, Intron 24, Silent 14, 5'UTR 4, 3'Flank 3, Nonsense Mutation 3, 5'Flank 3, Splice Site 2, Frame Shift Del 2, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.12031C>T p.R4011W | Missense Mutation (SNP) | VAF 84/155 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772310771, COSV71292500; called by muse, mutect2, varscan2
- ACCSL | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs752690708; called by muse, mutect2, varscan2
- CCDC92 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.636); catalogued as rs375777447; called by muse, mutect2, varscan2
- CHAC2 | c.135+1G>A p.X45_splice | Splice Site (SNP) | VAF 23/58 reads (40%) | catalogued as rs1187677389; called by muse, mutect2, varscan2
- CYP11A1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as rs1555425948, COSV51431898; called by muse, mutect2, varscan2
- DGKD | c.2263C>T p.L755= (on ENST00000264057 / NM_152879.3; = p.L711= on NM_003648.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 26/60 reads (43%) | catalogued as COSV51034518; called by muse, mutect2, varscan2
- DNHD1 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); catalogued as rs760108684; called by muse, mutect2, varscan2
- GAD2 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV52169605; called by muse, mutect2, varscan2
- H4C5 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV63486767; called by muse, mutect2, varscan2
- LRRN4 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs756574056; called by muse, mutect2, varscan2
- MCF2L | c.1397C>T p.T466M (on ENST00000375608; = p.T434M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs751741111, COSV65047726; called by muse, mutect2, varscan2
- MRC2 | c.3641C>T p.P1214L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs554348769; called by muse, mutect2, varscan2
- MYBBP1A | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs565454228, COSV54594520; called by muse, mutect2, varscan2
- MYH7 | c.4868A>G p.N1623S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.881); catalogued as rs1306407579; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.410G>T p.W137L | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV68015937; called by muse, mutect2, varscan2
- NTRK3 | c.1915del p.V640Wfs*53 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | catalogued as COSV62311237; called by mutect2, pindel, varscan2
- RFX7 | c.3642C>G p.F1214L (on ENST00000559447 / NM_001368074.1; = p.F1311L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV57965522; called by muse, mutect2
- RGS11 | c.1374T>A p.C458* (on ENST00000397770 / NM_183337.3; = p.C437* on NM_003834.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99396087; called by muse, mutect2, varscan2
- ROCK2 | c.3511G>A p.V1171I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs1231438319; called by muse, mutect2, varscan2
- RSPO4 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780874153, COSV54083503; called by muse, mutect2, varscan2
- SIPA1L2 | c.4978C>A p.Q1660K | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV99479494; called by muse, mutect2
- SMN1 | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1199331007, COSV100665254; called by muse, mutect2
- VWF | c.6442G>C p.A2148P | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV54611913; called by muse, varscan2
- ADCY5 | c.1095_1096del p.L366Afs*35 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- ADRA2C | c.656T>G p.F219C | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP12A | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CACHD1 | c.2194T>A p.Y732N | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CCDC168 | c.15434G>A p.R5145K | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CCDC182 | c.208T>G p.L70V | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CHD8 | c.2503G>A p.A835T (on ENST00000646647 / NM_001170629.2; = p.A556T on NM_020920.4) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHMP3 | c.101T>A p.I34K | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CYP2R1 | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- DBNDD2 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ENAM | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2
- EP300 | c.4462A>T p.K1488* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- FAM20C | c.1627C>A p.L543M | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM71F2 | c.887T>A p.V296D | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FAT3 | c.13504G>C p.V4502L | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT10 | c.1310G>A p.W437* | Nonsense Mutation (SNP) | VAF 50/168 reads (30%) | called by muse, mutect2, varscan2
- IL18R1 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- LILRB2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- METTL2B | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUSK | c.2426A>T p.E809V | Missense Mutation (SNP) | VAF 103/156 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYRFL | c.2378C>A p.S793Y | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PADI1 | c.1439T>C p.V480A | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- RALGPS2 | c.1019A>T p.K340M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASSF10 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 139/186 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SIPA1L2 | c.4979A>G p.Q1660R | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLITRK4 | c.2026A>T p.N676Y | Missense Mutation (SNP) | VAF 70/74 reads (95%) | SIFT tolerated (0.28); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- THAP9 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- TMC2 | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TTN | c.72703_72704insC p.V24235Afs*15 (on ENST00000591111; = p.V16811Afs*15 on NM_003319.4) | Frame Shift Ins (INS) | VAF 90/231 reads (39%) | called by mutect2, pindel, varscan2
- VPS54 | c.1009_1010+8del p.X337_splice | Splice Site (DEL) | VAF 30/59 reads (51%) | called by mutect2, pindel, varscan2
- ZAP70 | c.1684C>G p.P562A | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF701 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APOA4 | c.609C>A p.P203= | Silent (SNP) | VAF 10/245 reads (4%) | catalogued as COSV63361142, COSV63361244; called by muse, mutect2
- C1orf159 | c.1059G>A p.P353= (on ENST00000379339 / NM_001330306.2; = p.P171= on NM_017891.5) | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs532391088; called by muse, mutect2, varscan2
- FAT4 | c.13611A>G p.K4537= | Silent (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- GRM6 | c.1767G>A p.P589= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs754267755, COSV51432343; called by muse, mutect2, varscan2
- HLX | c.1032C>T p.D344= | Silent (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.294T>C p.A98= | Silent (SNP) | VAF 56/104 reads (54%) | catalogued as rs546240484; called by muse, mutect2, varscan2
- KCNAB3 | c.474C>G p.T158= | Silent (SNP) | VAF 61/64 reads (95%) | called by muse, mutect2, varscan2
- METTL6 | c.679C>T p.L227= | Silent (SNP) | VAF 109/153 reads (71%) | catalogued as rs1255279788; called by muse, mutect2, varscan2
- NELL2 | c.33C>G p.L11= | Silent (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- OR11L1 | c.21C>A p.S7= | Silent (SNP) | VAF 103/229 reads (45%) | called by muse, mutect2, varscan2
- RYR2 | c.2544C>T p.R848= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs748097250, COSV63683700; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMA3E | c.1389A>G p.V463= | Silent (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- SLC8A2 | c.765C>T p.Y255= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs1343377843; called by muse, mutect2, varscan2
- TRIM15 | c.400C>T p.L134= | Silent (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- ACADS | c.360+105C>T | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- ACTG2 | c.256-239T>G | Intron (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- ADD3-AS1 | chr10:109941610 C>A | 3'Flank (SNP) | VAF 79/168 reads (47%) | called by muse, mutect2, varscan2
- AICDA | c.*1135A>G | 3'UTR (SNP) | VAF 4/13 reads (31%) | catalogued as rs1269784425; called by muse, varscan2
- AL353804.7 | chrX:73846346 G>T | 5'Flank (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- ALG5 | c.66+79C>T | Intron (SNP) | VAF 19/23 reads (83%) | called by muse, mutect2, varscan2
- AMER3 | c.*2218C>T | 3'UTR (SNP) | VAF 60/149 reads (40%) | catalogued as rs1172287605; called by muse, mutect2, varscan2
- BMP6 | c.*612C>T | 3'UTR (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- BTBD9 | c.*4760C>A | 3'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- C11orf45 | c.-6G>A | 5'UTR (SNP) | VAF 69/207 reads (33%) | catalogued as rs368037087; called by muse, mutect2, varscan2
- CD1E | c.-16C>G | 5'UTR (SNP) | VAF 82/158 reads (52%) | catalogued as COSV100937020, COSV63770007; called by muse, mutect2, varscan2
- CHST15 | c.-317T>G | 5'UTR (SNP) | VAF 26/55 reads (47%) | catalogued as rs1425036697; called by muse, mutect2, varscan2
- DHFR2 | c.*1612G>T | 3'UTR (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- DTWD2 | c.*2398A>G | 3'UTR (SNP) | VAF 7/21 reads (33%) | catalogued as COSV58366270; called by muse, mutect2, varscan2
- DUSP18 | c.*448A>T | 3'UTR (SNP) | VAF 46/86 reads (53%) | called by muse, mutect2, varscan2
- DYRK2 | c.*4918_*4921del | 3'UTR (DEL) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- EIF4E3 | c.*5231G>A | 3'UTR (SNP) | VAF 49/159 reads (31%) | called by muse, mutect2, varscan2
- FAM107A | c.*2125A>G | 3'UTR (SNP) | VAF 31/107 reads (29%) | catalogued as rs1349617536; called by muse, mutect2, varscan2
- FAM189A1 | c.*998G>A | 3'UTR (SNP) | VAF 15/126 reads (12%) | catalogued as rs1260188522; called by muse, mutect2, varscan2
- FAM234A | chr16:234810 C>A | 5'Flank (SNP) | VAF 13/26 reads (50%) | catalogued as rs114516401, COSV56995119; called by muse, mutect2, varscan2
- GPR61 | chr1:109546685 T>G | 3'Flank (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- GRIA4 | c.487+44533C>A | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- IGHD1-1 | chr14:105922626 T>C | 5'Flank (SNP) | VAF 127/131 reads (97%) | called by muse, mutect2, varscan2
- ING3 | c.267+226_267+227insCGGTAACA | Intron (INS) | VAF 57/109 reads (52%) | called by mutect2, varscan2*
- JAG2 | c.*1288C>A | 3'UTR (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- KBTBD6 | c.*875T>A | 3'UTR (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- KIAA1549 | c.*2898T>G | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- LAMTOR3 | c.*2503G>C | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- LDHB | c.714-134G>C | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- LTB | c.163-26T>G | Intron (SNP) | VAF 134/272 reads (49%) | called by muse, varscan2
- LTB | c.163-27C>T | Intron (SNP) | VAF 134/270 reads (50%) | catalogued as rs565596357; called by muse, varscan2
- MAGI3 | c.553+20C>T | Intron (SNP) | VAF 34/68 reads (50%) | catalogued as rs760170611; called by muse, mutect2, varscan2
- NIBAN2 | c.*1233G>A | 3'UTR (SNP) | VAF 69/99 reads (70%) | called by muse, mutect2, varscan2
- NKX2-5 | c.335-276A>T | Intron (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- NPR2 | c.*283G>T | 3'UTR (SNP) | VAF 20/442 reads (5%) | called by muse, mutect2
- PDE3B | c.*765G>T | 3'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- PDP1 | c.-149G>C | 5'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1719+459T>C | Intron (SNP) | VAF 49/83 reads (59%) | called by muse, mutect2, varscan2
- PIK3R2 | c.*615A>G | 3'UTR (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- PLA2R1 | c.*3703T>G | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.1393-39C>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs1300151068; called by muse, mutect2, varscan2
- PSAP | c.1351-44G>A | Intron (SNP) | VAF 50/108 reads (46%) | catalogued as rs536532228; called by muse, mutect2, varscan2
- PVR | c.1150+183T>A | Intron (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- RBM23 | c.*707T>G | 3'UTR (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- RCC2 | chr1:17407586 G>A | 3'Flank (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- RGP1 | c.*3346G>T | 3'UTR (SNP) | VAF 11/127 reads (9%) | catalogued as rs946940387; called by muse, mutect2
- RNF141 | c.144-1110C>G | Intron (SNP) | VAF 17/49 reads (35%) | catalogued as rs1251849062; called by muse, mutect2, varscan2
- RUNX1T1 | c.1280-3945C>T | Intron (SNP) | VAF 23/46 reads (50%) | catalogued as rs996073184; called by muse, mutect2, varscan2
- SBK1 | c.*455A>G | 3'UTR (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
- SDHAF4 | c.*386del | 3'UTR (DEL) | VAF 4/26 reads (15%) | catalogued as rs759872733, COSV65085169; called by pindel, varscan2
- SLC26A8 | c.*154C>T | 3'UTR (SNP) | VAF 30/74 reads (41%) | catalogued as rs1000524052; called by muse, mutect2, varscan2
- SLC45A1 | c.*56C>A | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- SLC6A3 | c.*1596G>T | 3'UTR (SNP) | VAF 60/130 reads (46%) | called by muse, mutect2, varscan2
- SNX29 | c.1124+346G>T | Intron (SNP) | VAF 20/160 reads (13%) | called by muse, varscan2
- STT3B | c.*1224A>G | 3'UTR (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- TBC1D26 | c.546+290G>A | Intron (SNP) | VAF 8/85 reads (9%) | catalogued as rs1280370961; called by muse, mutect2, varscan2
- TDGF1P3 | n.789C>T | RNA (SNP) | VAF 90/99 reads (91%) | called by muse, mutect2, varscan2
- TEDDM1 | c.*829T>A | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- TMEM106B | c.*1230T>C | 3'UTR (SNP) | VAF 9/49 reads (18%) | catalogued as rs773437170; called by muse, mutect2, varscan2
- TMEM263 | c.*1361T>C | 3'UTR (SNP) | VAF 46/99 reads (46%) | called by muse, mutect2, varscan2
- TMEM50B | c.*538G>A | 3'UTR (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2
- TPSG1 | c.47-88G>T | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- TTC22 | c.1020+576A>G | Intron (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- UBE2E3 | c.195-31T>A | Intron (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- WDTC1 | c.1643+46G>A | Intron (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- YPEL4 | c.185+18C>T | Intron (SNP) | VAF 57/222 reads (26%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.*794A>G | 3'UTR (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- ZNF192P1 | n.1168C>T | RNA (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.49+10G>A | Intron (SNP) | VAF 58/186 reads (31%) | called by muse, mutect2, varscan2
